Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4JW, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4JW-01A (Primary Tumor).

JOB: _____ Sex: F
Physician: _____
Accession: _____

Collector: _____
Received: _____ Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Right lobe
Multi-focal: No
Size = 1.6 cm
Extrathyroidal extension: Absent
Lymphovascular invasion: Absent
Resection Margins: Negative
Background Thyroid: Focal chronic lymphocytic thyroiditis
Lymph nodes: No tumor present in one lymph node (0/1)

ICD-O-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
JW
10/4/12

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY, STITCH RIGHT LOBE - The specimen consists of a thyroid with a right thyroid lobe (5.8 x 2.3 x 2.2 cm), left thyroid lobe (4.7 x 2.0 x 1.9 cm) and an isthmus (1.7 x 1.5 x 0.4 cm). The outer surface is tan-red, smooth with no grossly identifiable lesion.

The specimen is serially sectioned. There is a tan-pink, hemorrhagic soft, fairly well-circumscribed nodule located in the mid portion of the right lobe (1.6 x 1.5 x 0.6 cm) approximately 0.2 cm from the closest margin. There is also a firm, well-circumscribed smaller nodule located in the superior portion of the right thyroid lobe (0.6 x 0.5 x 0.3 cm). The remaining portion of the thyroid is grossly unremarkable.

SECTION CODE: A1-A8, the right thyroid lobe, submitted from superior towards inferior aspect (A1 contains the smaller nodule in the superior aspect; A3-A6, contain the larger nodule in the mid portion of the right lobe); A9, A10, isthmus, submitted from right towards left; A11-A13, representative sections of the left thyroid lobe submitted from superior towards inferior aspect. A portion of normal thyroid and the lesion was submitted to tumor tissue bank for research.

CLINICAL HISTORY

Papillary thyroid carcinoma.

SNOMED CODES

T-B6000, M-80503,

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report
File under: Pathology

Discrepancy/Synchronous Primary Tumor		✓

Source: NCI Genomic Data Commons file 4d5b4143-eb24-4e32-a666-55a835dd4039 (TCGA-EL-A4JW.63B98E77-2C2B-4767-9D06-D5C6BC5011D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).